TCGA case TCGA-FF-A7CR — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: SingHealth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f784bc3a-751b-4025-aab2-0af2f6f24266

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Singapore; Age at index: 61 years; Vital status: Dead; Days to death: 313 days.

Diagnoses (3)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 61.5 years (22,471 days); Year of diagnosis: 2012; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 313 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Inguinal / Lymph Node, Retroperitoneal / Brain, NOS / Sinus.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 3 cm; Measurement unit: Centimeters.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 7 days; Days to treatment end: 277 days; Number of cycles: 5.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 193 days; Days to treatment end: 256 days; Number of cycles: 2.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.
2. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Skin, NOS. Age at diagnosis: 62.3 years (22,761 days); Days to diagnosis: 290 days; Prior treatment: Yes.
3. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Bone marrow. Age at diagnosis: 62.3 years (22,761 days); Days to diagnosis: 290 days; Prior treatment: Yes.

Follow-up (5 entries)
- Day 290 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone marrow; Days to progression: 290 days.
- Day 290 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin, NOS; Days to progression: 290 days.
- Days to follow up: 313 days; Disease response: With Tumor.
- ECOG performance status: 0.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- BCL10 (FISH): Normal.
- BCL2 (FISH): Normal.
- BCL2 (IHC): Positive.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Positive.
- CCND1 (FISH): Normal.
- CCND1 (IHC): Negative.
- CD10 (IHC): Negative.
- CD138 (IHC): Positive.
- CD20 (IHC): Positive.
- CD23 (IHC): Positive.
- CD30 (IHC): Negative.
- CD5 (IHC): Positive.
- FOXP1 (FISH): Normal.
- IGH translocation (FISH): Positive.
- IRF4 (IHC): Positive.
- MALT1 (FISH): Normal.
- MYC (FISH): Normal.
- PAX5 (FISH): Normal.
- Lactate Dehydrogenase 446 IU [Blood test normal range upper: 380].
- Epstein-Barr Virus (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 170 cm; BMI: 25.3.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis C Infection.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FF-A7CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 360 mg.
  Slide TCGA-FF-A7CR-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 35; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-FF-A7CR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Treatment outcome first course: Progressive Disease.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 2.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Axillary; Lymph node involvement site: cervical; Lymph node involvement site: Inguinal; Lymph node involvement site: retroperitoneal.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Brain; Submitted tumor site: Sinus.
- Tests performed: LDH level: 446; Mib 1 positive percent range: 0 - 25%.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: CD138; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: BCL6 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: CD23; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunopheotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunopheotypic analysis tested: Eber; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunopheotypic analysis tested: Cyclin D1; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc; Genetic abnormality tested other: PAX5.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2; Genetic abnormality tested other: IGH.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6; Genetic abnormality tested other: FoxP1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 4: Genetic abnormality tested: CCND1; Genetic abnormality tested other: BCL10.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 5: Genetic abnormality tested: MALT1.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Tumor status: With tumor.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, Methotrexate.
- Drug treatment 3: Pharmaceutical therapy drug name: Oncovin; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, Methotrexate.
- Drug treatment 4: Pharmaceutical therapy drug name: Prednisolone; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, Methotrexate.
- Drug treatment 6: Pharmaceutical therapy drug name: Hydroxydaunomycin; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, Methotrexate.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 313 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 313 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 290 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FF-A7CR-01A-11D-A381-01): tumor purity 0.48, ploidy 2.03, whole-genome doublings 0.
